Somatic mutation profile of tumor specimen TCGA-XK-AAJT-01A (aliquot TCGA-XK-AAJT-01A-11D-A41K-08) from TCGA case TCGA-XK-AAJT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 75.1 years (27,428 days).
Specimen TCGA-XK-AAJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b536dc37-1243-4cf8-bcf0-ff59ecf4a832.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAJT-10A (Blood Derived Normal), aliquot TCGA-XK-AAJT-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/142c7e84-d294-4117-a648-a7db6120960f

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376945285; called by muse, mutect2, varscan2
- ASIC2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1478070663, COSV99859937; called by muse, mutect2, varscan2
- DCAF10 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV99647662; called by muse, mutect2, varscan2
- EVI2B | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100445457; called by muse, mutect2, varscan2
- GJA3 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1400267320, COSV99576348; called by muse, mutect2, varscan2
- GJA5 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs782278675, COSV99605512; called by muse, mutect2, varscan2
- HMCN1 | c.13454G>A p.R4485Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374051668, COSV54876527; called by muse, mutect2, varscan2
- HUWE1 | c.7852C>G p.R2618G | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99471099, COSV99471864; called by muse, mutect2, varscan2
- LPCAT4 | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100148979; called by muse, mutect2, varscan2
- MRPL14 | c.43A>G p.S15G | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV100921037; called by muse, mutect2, varscan2
- NGF | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1043758056, COSV65688042; called by muse, mutect2, varscan2
- PCDH10 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.417); catalogued as rs1463716573, COSV99993444; called by muse, mutect2, varscan2
- PDK1 | c.1013C>G p.T338S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99961263; called by muse, mutect2, varscan2
- PLEKHH2 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99174691; called by muse, mutect2
- PSG3 | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100548936; called by muse, mutect2
- RYR2 | c.12256C>T p.R4086C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1251459666, COSV63678730; called by muse, mutect2, varscan2
- SBSPON | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866466373, COSV52076547; called by muse, mutect2, varscan2
- TRMT10C | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463755571, COSV99998280; called by muse, mutect2, varscan2
- ZNF33A | c.586A>G p.R196G (on ENST00000458705 / NM_006974.3; = p.R197G on NM_006954.2) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1364101356, COSV100275735; called by muse, mutect2, varscan2
- NCAPD3 | c.2335+1_2335+3del p.X779_splice | Splice Site (DEL) | VAF 106/320 reads (33%) | called by pindel, varscan2
- PLEC | c.12304_12305insTA p.E4102Vfs*20 (on ENST00000322810 / NM_201380.4; = p.E3992Vfs*20 on NM_000445.5) | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel*, varscan2
- DGKA | c.840G>A p.G280= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100092994; called by muse, mutect2, varscan2
- KCNH4 | c.1578C>T p.I526= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1303724921, COSV52915277; called by muse, mutect2, varscan2
- NUDCD2 | c.87C>T p.F29= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs988820400, COSV100243579; called by muse, mutect2, varscan2
- PCARE | c.690C>T p.S230= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100527492; called by muse, mutect2, varscan2
- RFX7 | c.2778G>A p.P926= (on ENST00000559447 / NM_001368074.1; = p.P1023= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs373394346; called by muse, mutect2, varscan2
